Gene-level copy-number profile of tumor specimen TCGA-EE-A2M8-06A from TCGA case TCGA-EE-A2M8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.4 years (20,221 days).
Specimen TCGA-EE-A2M8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.394eff98-a443-4ff4-a0e3-9e3afb8a4106.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2M8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21e269e4-08f4-405c-b6e8-fb23ddf46109

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,536; copy number 2: 45,307; copy number 3: 1,739; copy number 4: 2,229; copy number 5: 1,009.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2M8-06A-12D-A194-01): tumor purity 0.25, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,009 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:107,044,705–159,233,377, 1,009 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,536. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
